Gene-level copy-number profile of tumor specimen TCGA-24-1471-01A from TCGA case TCGA-24-1471, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.5 years (22,081 days).
Specimen TCGA-24-1471-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.20ca8b0a-b561-405f-89d4-5f12f40a5455.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1471-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d684bbb-45a4-4dd3-be6d-9df5837c8929

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,636; copy number 2: 27,030; copy number 3: 18,325; copy number 4: 8,379; copy number 5: 1,149; copy number 6: 116; copy number 8: 180.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1471-01A-01D-0497-01): tumor purity 0.89, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,445 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:19,484,403–19,629,821, 1 gene, copy number 5 (within-gene range 4–5): MICOS10.
- chr1:19,591,802–19,680,966, 5 genes, copy number 5: AL031727.2, NBL1, MICOS10-NBL1, AL031727.1, HTR6.
- chr1:202,096,759–248,919,946, 1,073 genes, copy number 5 (broad region; genes not listed).
- chr3:96,244,732–103,160,124, 119 genes, copy number 5–6 (broad region; genes not listed).
- chr3:105,655,461–109,410,084, 61 genes, copy number 5 (broad region; genes not listed).
- chr3:109,471,329–109,471,812, 1 gene, copy number 5: PPIAP15.
- chr3:164,171,471–178,385,479, 180 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr3:188,107,072–188,154,057, 2 genes, copy number 5 (within-gene range 3–5): AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 5: FLJ42393.
- chr5:73,552,190–73,583,380, 2 genes, copy number 5: ANKRA2, UTP15.

Autosomal genes at a single copy (total copy number 1): 2,215. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
